Surgical pathology report (de-identified scan), TCGA case TCGA-J4-A67Q, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-A67Q-01A (Primary Tumor).

[page 1 of 3]
MRN _____ Gender **M**
Name _____ Date Of Birth _____
Encounter Number _____

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected _____ Time Received _____
Time Reported _____ Order Number _____
Ordering Provider _____
Status _____ Final

Results

Final

Source of Specimen
A. TISSUE OVER PROSTATE-
B. PROSTATE GLAND SEMINAL VESICLES VAS DEFERENS-

FINAL DIAGNOSIS:
A. TISSUE OVER PROSTATE-
ADIPOSE TISSUE.
NO TUMOR SEEN.
B. PROSTATE GLAND SEMINAL VESICLES VAS DEFERENS-
ADENOCARCINOMA OF PROSTATE. NO EXTRAPROSTATIC EXTENSION SEEN.

TUMOR SITE: LEFT AND RIGHT SIDES.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 38 GRAMS.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 3 + 3 = 6/10.

TNM STAGE: pT2c, pNX, pMX.

PERINEURAL INVASION: NOT PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

NO TUMOR SEEN AT SPECIMEN MARGINS.

Signature _____

Prepared for _____

hw 4/22/13

Criteria	P-3 (6) white	No
Hi/PA Discrepancy		
Dual/Synchronous Findings Noted		
Case Is (clin. e)		

path
ICD-O-3
Adenocarcinoma NOS 8140/3
Adenocarcinoma, Acinar 8140/3
Site: Prostate NOS C61.9
QJ 5/9/13

[page 2 of 3]
Case Clinical Information
PROSTATE CANCER

Gross Description

A. Received in formalin labeled with the patient's name and "tissue over prostate" are yellow fibrofatty tissue fragments measuring 2.0 x 1.5 x 0.3 cm. No lymph nodes or areas of induration are grossly identified. The specimen is submitted complete in A1-A2.

B. Received in formalin labeled with the patient's name and "prostate gland seminal vesicle, vas deferens" is a radical prostatectomy specimen which includes a 38 gram prostate gland with attached seminal vesicle and vas deferens. The prostate gland measures 4.0 x 3.5 x 3.0 cm and has a shaggy capsule that is disrupted at the bladder resection margin and has been previously inked black on the left and blue on the right. The right seminal vesicle measures 2.0 x 1.0 cm. The right vas measures 3.0 x 0.5 cm. The left seminal vesicle measures 3.0 x 1.5 cm. The left vas measures 4.0 x 0.5 cm. The inferior prostate is sectioned transversely, removed from the rest of the specimen and sectioned from anterior to posterior following the plane of the urethra. The remaining gland is serially sectioned transversely and shows a firm, focally nodular parenchyma. The seminal vesicles and vasa deferentia show no abnormalities. Representative sections submitted as follows: inferior prostate demonstrating apical margin submitted entirely anterior to posterior in B1-B6 ; bladder resection margin submitted in B7-B8; complete section of mid gland anterior B9-B10; posterior B11-B12; complete section of upper third of gland, anterior B13-B14; posterior B15-B16; remainder of the posterior gland entirely submitted in B17-B22; right seminal vesicle and vas deferens B23; left seminal vesicle and vas deferens B24. Also there are two research blocks which are submitted.

Physicians

Procedure

A. AA ROUTINE H&E X1 BLOCK.1

H&E X1

A. AA ROUTINE H&E X1 BLOCK.2

H&E X1

B. AA ROUTINE H&E X1 BLOCK.1

H&E X1

Prepared for

[page 3 of 3]
B. AA ROUTINE H&E X1 BLOCK.2
H&E X1
B. AA ROUTINE H&E X1 BLOCK.3
H&E X1
B. AA ROUTINE H&E X1 BLOCK.4
H&E X1
B. AA ROUTINE H&E X1 BLOCK.5
H&E X1
B. AA ROUTINE H&E X1 BLOCK.6
H&E X1
B. AA ROUTINE H&E X1 BLOCK.7
H&E X1
B. AA ROUTINE H&E X1 BLOCK.8
H&E X1
B. AA ROUTINE H&E X1 BLOCK.9
H&E X1
B. AA ROUTINE H&E X1 BLOCK.10
H&E X1
B. AA ROUTINE H&E X1 BLOCK.11
H&E X1
B. AA ROUTINE H&E X1 BLOCK.12
H&E X1
B. AA ROUTINE H&E X1 BLOCK.13
H&E X1
B. AA ROUTINE H&E X1 BLOCK.14
H&E X1
B. AA ROUTINE H&E X1 BLOCK.15
H&E X1
B. AA ROUTINE H&E X1 BLOCK.16
H&E X1
B. AA ROUTINE H&E X1 BLOCK.17
H&E X1
B. AA ROUTINE H&E X1 BLOCK.18
H&E X1
B. AA ROUTINE H&E X1 BLOCK.19
H&E X1
B. AA ROUTINE H&E X1 BLOCK.20
H&E X1
B. AA ROUTINE H&E X1 BLOCK.21
H&E X1
B. AA ROUTINE H&E X1 BLOCK.22
H&E X1
B. AA ROUTINE H&E X1 BLOCK.23
H&E X1
B. AA ROUTINE H&E X1 BLOCK.24
H&E X1

Prepared for.

Source: NCI Genomic Data Commons file a7e6f28b-d085-4366-9ea3-5f6db97806ad (TCGA-J4-A67Q.E7702E20-7616-4A88-862B-E860045E9C81.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).